Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A56S, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A56S-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Malignant Mullerian Mixed Tumor
895013

Site
Path: Uterus, Corpus Uteri
C54.9

C&CF: Endometrium
C54.1
12/14/12 Jue

Diagnosis:

A: Uterus, cervix and bilateral adnexa, hysterectomy and
bilateral salpingo-oophorectomy:

Histologic type: Malignant mixed Mullerian tumor/carcinosarcoma
with heterologous (cartilaginous) elements.

Histologic grade: FIGO Grade 3.

Tumor site: Anterior and posterior corpus and lower uterine
segment and anterior endometrial polyp.

Myometrial invasion: Outer half (A5).

Depth: 1.7 cm Wall thickness: 1.8 cm Percent: 94%

Serosal involvement: Absent.

Lower uterine segment involvement: Present.

Cervical involvement: Absent.

Adnexal involvement: Absent.

Cervical/vaginal margin and distance: Widely negative.

Lymphovascular space invasion: Present.

Regional lymph nodes: Not submitted.

Additional pathologic findings:

Cervix: Nabothian cysts.

Endometrium: Background atrophic pattern.

Myometrium: Hyalinized leiomyomata (up to 1.0 cm).

Right ovary: Benign inclusion cysts and physiologic changes.

Left ovary: Benign inclusion cysts, dystrophic calcification and
physiologic changes.

Right fallopian tube: Benign paratubal cysts and unremarkable
lumen.

Left fallopian tube: Unremarkable.

AJCC Pathologic Stage: pT1b pNX pMX

FIGO (2009 classification) Stage Grouping: IB

Note: This pathologic stage assessment is based on information
available at the time of this report, and is subject to change
pending clinical review and additional information.

[page 2 of 3]
B: Omentum, omentectomy:

- Lipoma with fat necrosis and calcifications.
- No malignancy identified.

Clinical History:

-year-old female with a pelvic mass.

Gross Description:

Received are two appropriately labeled containers.

Container A:

Adnexa: bilateral tubes and ovaries are present and detached

Weight: 380 grams

Shape: pear shaped

Dimensions:

height: 12.5 cm

anterior to posterior width: 7.4 cm

breadth at fundus: 7.3 cm

Serosa: tan/pink, smooth and glistening

Cervix: 2.5 x 2.4 x 1.5 cm

ectocervix: tan/white, smooth and glistening

endocervix: red/tan and trabeculated

length of endocervical canal: 2.1 cm

Endomyometrium:

length of endometrial cavity: 7.5 cm

width of endometrial cavity at fundus: 5.2 cm

tumor findings:

dimensions: 6.1 x 6.0 x 3.1 cm

appearance: The tumor is tan/white and solid with focal areas of necrosis and hemorrhage.

location and extent: The tumor appears to involve the anterior and posterior upper and mid corpus as well as the lower uterine segment.

myometrial invasion: outer one-half

thickness of myometrial wall at deepest gross invasion: 1.8 cm

other findings or comments: There are three subserosal and intramural tan/white firm rubbery nodules within the anterior uterus ranging in largest diameter from 0.3 to 1.0 cm. The cut surface of these nodules are tan/white and whorled in appearance. In addition, there is an endometrial polyp within the anterior lower uterine segment measuring 0.6 cm in diameter.

Adnexa:

Right ovary:

dimensions: 2.1 x 1.2 x 0.5 cm

external surface: tan/white and cerebriform

cut surface: unremarkable

Right fallopian tube:

dimensions: 5.2 cm in length, 1.0 cm in diameter

[page 3 of 3]
other findings: On the external surface is a yellow/tan raised nodule measuring 0.1 cm in diameter. Sectioning of the tube reveals a patent lumen. In addition, tubal ligation device is present.

Left ovary:

dimensions: 2.2 x 1.5 x 0.5 cm

external surface: tan/pink and cerebriform

cut surface: unremarkable

Left fallopian tube:

dimensions: 4.5 cm in length, 0.7 cm in diameter

other findings: Tubal ligation devices are present; sectioning of the tube reveals a patent lumen

Lymph nodes: n/a

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: Tumor is given to Tissue Procurement.

Block Summary:

A1 - anterior cervix

A2 - endometrial polyp from anterior lower uterine segment

A3 - additional section of anterior lower uterine segment

A4,A5 - anterior mid corpus, bisected

A6,A7 - anterior upper corpus/fundus

A8 - representative sections of subserosal nodules

A9 - posterior cervix

A10 - posterior lower uterine segment

A11,A12 - posterior mid corpus, bisected

A13,A14 posterior upper corpus/fundus, bisected

A15 - representative section of posterior intramural nodule

A16 - right ovary

A17 - right fallopian tube

A18 - left ovary

A19 - left fallopian tube

Container B is additionally labeled "omentum." It holds a section of omentum measuring 17.1 x 7.1 x 0.9 cm. The omentum is serially sectioned to reveal one mass measuring 1.5 x 1.2 x 0.7 cm. The mass is well circumscribed and tan/white and sectioning reveals areas of necrosis. The remainder of tissue consists of yellow/tan adipose tissue with no other masses or lesions identified.

Block summary:

B1 - sections of mass

B2,B3 - representative sections of remainder of tissue

Reviewer Initials	W, 2/13/2	2/13/2

Source: NCI Genomic Data Commons file adef44bb-2bf2-404a-97af-61f368de3b83 (TCGA-N8-A56S.59082C41-B569-4EC1-9D1C-2B21D69A7F60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).